Somatic mutation profile of tumor specimen TCGA-MU-A5YI-01A (aliquot TCGA-MU-A5YI-01A-11D-A32I-09) from TCGA case TCGA-MU-A5YI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IA1; Tumor grade: G2; Age at diagnosis: 60.0 years (21,927 days).
Specimen TCGA-MU-A5YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 281a3e30-66a1-4a85-9ccd-53f7f752d2c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MU-A5YI-10A (Blood Derived Normal), aliquot TCGA-MU-A5YI-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/802d8ca0-1566-47cb-b521-04e09afa1541

The open-access MAF lists 67 somatic variants for this specimen: 43 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Nonsense Mutation 3, RNA 2, Frame Shift Del 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as rs121434545, CM950189, COSV58826545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99711827; called by muse, mutect2, varscan2
- AHDC1 | c.3857G>A p.R1286Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs377405108; called by muse, mutect2, varscan2
- ARHGAP31 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51798948; called by muse, mutect2, varscan2
- ARPC2 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV55286616; called by muse, mutect2, varscan2
- ATPAF2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.063); catalogued as rs777247426, COSV71398542; called by muse, mutect2, varscan2
- BRWD3 | c.4565C>T p.S1522L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs374994843, COSV64753853; called by muse, mutect2
- CHD7 | c.3221C>A p.S1074Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.522); catalogued as COSV101417940; called by muse, mutect2, varscan2
- CLPB | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV53633857; called by muse, mutect2, varscan2
- CNTNAP2 | c.3473T>C p.I1158T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs1064794544, COSV62261029; called by muse, mutect2, varscan2
- CPNE1 | c.535G>A p.E179K (on ENST00000352393; = p.E184K on NM_003915.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1320419948, COSV58295247; called by muse, mutect2, varscan2
- DDX21 | c.1933A>G p.I645V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs201054642; called by muse, mutect2, varscan2
- E2F8 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.172); catalogued as COSV51466262; called by muse, mutect2, varscan2
- FUT1 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV59570091; called by muse, mutect2, varscan2
- GAA | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV56412303; called by muse, mutect2, varscan2
- GJD2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs775572644, COSV51748301, COSV51750051; called by muse, mutect2, varscan2
- INSC | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs780403672, COSV65411409, COSV65413314; called by muse, mutect2, varscan2
- LIG4 | c.2452G>A p.V818I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs534543979, COSV63596423; called by mutect2, varscan2
- MDC1 | c.1280G>A p.W427* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100903065, COSV64527763; called by muse, mutect2, varscan2
- NAV3 | c.1950C>A p.D650E | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57113359; called by muse, mutect2, varscan2
- NEB | c.17564T>A p.V5855D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV51461118; called by muse, mutect2, varscan2
- NHS | c.1758C>G p.I586M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV66282913; called by muse, mutect2, varscan2
- NOD2 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.222); catalogued as rs760938311, COSV56053693; called by muse, mutect2, varscan2
- NOTCH1 | c.1400G>A p.C467Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429314606, COSV53030917, COSV53042420; called by muse, mutect2, varscan2
- PAWR | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 31/44 reads (70%) | catalogued as rs1329211453, COSV60925056; called by muse, mutect2, varscan2
- PCDHA2 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as COSV65369662; called by muse, mutect2, varscan2
- PGLYRP4 | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV62836442; called by muse, mutect2, varscan2
- POGZ | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV51853333; called by muse, mutect2, varscan2
- PRSS58 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73488870; called by muse, mutect2, varscan2
- PSPC1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs780662375, COSV58891109; called by muse, mutect2, varscan2
- RPE65 | c.597T>A p.N199K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs141527042, COSV52014131; called by muse, mutect2, varscan2
- SCAF4 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.787); catalogued as COSV54592486; called by muse, mutect2
- SCN8A | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.339); catalogued as COSV61993393; called by muse, mutect2, varscan2
- SLC25A44 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754955888, COSV63961861; called by muse, mutect2, varscan2
- SLC38A3 | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.091); catalogued as COSV68844182; called by muse, mutect2, varscan2
- SLC38A5 | c.1296C>G p.F432L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58335657; called by muse, mutect2, varscan2
- SOCS6 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV67547192; called by muse, mutect2, varscan2
- SOX5 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1217393451, COSV58638317; called by muse, mutect2, varscan2
- TDRD6 | c.5524G>C p.D1842H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV60178946; called by muse, mutect2, varscan2
- TTN | c.61321G>C p.D20441H (on ENST00000591111; = p.D13017H on NM_003319.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | PolyPhen possibly damaging (0.808); catalogued as COSV60360636; called by muse, mutect2, varscan2
- ZNF609 | c.2364C>G p.I788M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV58590427; called by muse, mutect2, varscan2
- BAZ2A | c.4922_4933del p.I1641_R1645delinsS | In Frame Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MRPL53 | c.137_138del p.N46Tfs*12 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ARMC12 | c.642C>T p.S214= (on ENST00000373866 / NM_001286574.2; = p.S241= on NM_145028.5) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV55361812; called by muse, mutect2, varscan2
- CFP | c.753G>T p.L251= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV55951472; called by muse, mutect2, varscan2
- FSHR | c.1125G>A p.L375= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs755003829, COSV58635458; called by muse, mutect2, varscan2
- GPC3 | c.1419G>A p.L473= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV63672344; called by muse, mutect2, varscan2
- JAKMIP2 | c.342C>T p.L114= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1379834776, COSV54615874; called by muse, mutect2, varscan2
- KIAA1191 | c.876C>G p.L292= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53800219; called by muse, mutect2, varscan2
- KIDINS220 | c.2029C>T p.L677= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV56759326; called by muse, mutect2, varscan2
- MICAL3 | c.306C>T p.A102= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52899621; called by muse, mutect2, varscan2
- NHS | c.1908C>G p.L636= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV66282930; called by muse, mutect2, varscan2
- NLGN4X | c.726C>T p.G242= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as rs753558783, COSV52037633; called by muse, mutect2, varscan2
- OAS3 | c.2103C>T p.P701= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as rs763844220, COSV57449556; called by muse, mutect2, varscan2
- PPP1R3A | c.2454G>A p.E818= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV52893597; called by muse, mutect2, varscan2
- RB1CC1 | c.1929G>C p.V643= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV50276247; called by muse, mutect2, varscan2
- RICTOR | c.2427C>T p.L809= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1437204026, COSV57131015; called by muse, mutect2, varscan2
- SCUBE2 | c.1335G>A p.V445= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs535859288, COSV58546948; called by mutect2, varscan2
- SLK | c.12C>T p.F4= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100211390; called by muse, mutect2, varscan2
- TMEM104 | c.1341G>A p.R447= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV59112403; called by muse, mutect2, varscan2
- UBR4 | c.15537G>A p.L5179= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV64399683; called by muse, mutect2, varscan2
- UNC79 | c.1704C>T p.R568= (on ENST00000393151 / NM_001346218.2; = p.R391= on NM_020818.5) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV56412087; called by muse, mutect2, varscan2
- USP22 | c.759G>A p.R253= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV54949116; called by muse, mutect2, varscan2
- ZNF688 | c.660C>T p.F220= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV56301990; called by muse, mutect2, varscan2
- AC024940.1 | n.5532G>A | RNA (SNP) | VAF 20/80 reads (25%) | catalogued as rs571934609; called by muse, mutect2, varscan2
- EPDR1 | c.-281G>C | 5'UTR (SNP) | VAF 22/72 reads (31%) | catalogued as COSV52262022; called by muse, mutect2, varscan2
- LRP5L | n.698G>A | RNA (SNP) | VAF 24/72 reads (33%) | catalogued as rs868414818, COSV68602482; called by muse, mutect2, varscan2
